Somatic mutation profile of tumor specimen BA2234D (aliquot aq-BA2234D) from BEATAML1.0 case 2247, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Therapy related myeloid neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.2 years (26,353 days).
Specimen BA2234D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2bd1e93-3909-4b46-9d13-df9aa3a2d430.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2118D (Solid Tissue Normal), aliquot aq-BA2118D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2d02a4d-e61a-412f-b66a-017dceb98e44

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMBT1 | c.5818C>A p.L1940M (on ENST00000338354 / NM_001377530.1; = p.L1183M on NM_004406.3) | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV57543952; called by muse, mutect2
- ZFYVE28 | c.1520G>T p.R507L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV52118272; called by muse, mutect2
- ACTN3 | c.1981C>A p.Q661K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2
- HS3ST6 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- OPLAH | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2
- KIF17 | c.1812G>T p.V604= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
